Gene-level copy-number profile of tumor specimen TCGA-AB-2804-03A from TCGA case TCGA-AB-2804, project TCGA-LAML (Acute Myeloid Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute promyelocytic leukaemia, t(15;17)(q22;q11-12); Tissue or organ of origin: Bone marrow; Age at diagnosis: 30.7 years (11,203 days).
Specimen TCGA-AB-2804-03A: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LAML.655ea425-64a1-45f9-bee4-576954ecf99a.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AB-2804-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 352 have no estimate.
https://portal.gdc.cancer.gov/files/4ec0d305-f238-4da4-a7a0-f20defe69201

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 2,395; copy number 1: 977; copy number 2: 56,078; copy number 3: 568; copy number 4: 195; copy number 5: 43; copy number 6: 14; copy number 10: 1.

Homozygous deletions (total copy number 0; autosomes only): 8 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:38,496,127–38,542,161, 3 genes (within-gene range 0–2): EXOG, Y_RNA, DDTP1.
- chr5:180,967,189–181,006,727, 4 genes (within-gene range 0–2): AC091874.2, AC091874.1, ARPP19P1, BTNL3.
- chr17:6,207,163–6,207,269, 1 gene: RNU6-1264P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 58 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:72,301,472–72,301,829, 1 gene, copy number 10: RPL31P12.
- chr4:189,940,870–190,092,279, 21 genes, copy number 5: FRG1, MLLT10P2, AF146191.2, TUBB7P, RNA5SP174, RNA5SP175, DUX4L9, FRG2, RARRES2P4, AGGF1P1, CLUHP4, DBET, U85056.1, DUX4L8, DUX4L7, DUX4L6, DUX4L5, DUX4L4, DUX4L1, DUX4L3, DUX4L2.
- chr7:76,818,377–77,198,626, 17 genes, copy number 5 (within-gene range 2–5): AC006972.1, AC007003.1, DTX2P1-UPK3BP1-PMS2P11, FDPSP7, AC114737.1, DTX2P1, UPK3BP1, PMS2P11, Y_RNA, SPDYE17, PMS2P9, Y_RNA, AC007000.3, SPDYE18, AC007000.2, FAM185BP, AC007000.1.
- chr7:158,730,995–159,144,867, 5 genes, copy number 5 (within-gene range 2–5): ESYT2, DYNC2I1, AC004863.1, LINC00689, VIPR2.
- chr11:11,570,084–11,573,782, 1 gene, copy number 6 (within-gene range 2–6): AC104031.1.
- chr15:25,056,860–25,081,378, 13 genes, copy number 6: SNORD116-3, SNORD116-4, SNORD116-5, SNORD116-6, SNORD116-7, SNORD116-8, SNORD116-9, SNORD116-10, SNORD116-11, SNORD116-12, SNORD116-13, SNORD116-14, SNORD116-15.

Autosomal genes at a single copy (total copy number 1): 977. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
